Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JT, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JT-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, mixed w/ other types, infiltrative. ductal 8523/3
(w/ papillary)
Site - Breast, NOS C50.9

3/11/11

h

page 1 / 2

Department of Cancer Pathology

copy No. 5

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Age: Gender: .

Material: Multiple organ resection – left breast

Unit in charge

Physician in charge:

Material collected on: Material received or

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the left breast.

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by

Score = 2+, verification by the FISH method recommended.

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 26 x 20 x 5.5 cm removed along with axillary tissues sized 10 x 8 x 2.5 cm and a 25 x 14 cm skin flap. Tumour sized 2.6 x 2 x 1.8 cm found in the outer lower quadrant, 5.3 cm from the lower boundary, 1.2 cm from the base and 1.4 cm from the skin.

Microscopic description:

Carcinoma ductale partim papillare – NHG1 (2 + 2 + 3/22 mitoses/ 10 HPF, visual area diameter: 0.55 m).

Glandular tissue showing lesions of the type fibrosa et cystica, hyperplasia ductalis simplex

Invasive lesions reaching the base.

Axillary lymph nodes:

Lymphonodulitis chronica et lymphonodorum No XV.

Compliance validated by:

Primary, Tumor Site Discrepancy		☒
Discrepancy Primary, Merged		☒
Case Rejection	☒	☐

[page 2 of 2]
Examination: Histopathological examination (

page 2 / 2

Examination No.

Patient: XXX

Gender

Examination performed on:

Results of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by

HER2 DNA Probe Kit

FINAL RESULT:

HER-2 gene AMPLIFICATION NOT FOUND.

Histopathological diagnosis:

Mixed ductal and papillary invasive carcinoma of the left breast. Usual ductal hyperplasia (). Fibrocystic changes. Lymph nodes negative for cancer.

Compliance validated by:

Source: NCI Genomic Data Commons file 04fe90f7-5b74-4ee3-bff6-37053a42ae50 (TCGA-D8-A1JT.72AF26A2-FAD0-42FD-A63C-6E8E2597B84E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).